Surgical pathology report (de-identified scan), TCGA case TCGA-61-2110, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2110-01A (Primary Tumor).

FINAL DIAGNOSIS:

FINAL DIAGNOSIS:

LEFT ADNEXA:

- OVARY WITH PAPILLARY SEROUS ADENOCARCINOMA FOCALLY ASSOCIATED WITH A LOW MALIGNANT POTENTIAL COMPONENT
- B&BFS) BLADDER BIOPSY:
- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA
- C) CUL-DE-SAC BIOPSY:
- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA
- D) UTERUS WITH RIGHT ADNEXA, 160 GRAMS:
- CHRONIC CYSTIC CERVICITIS WITH SQUAMOUS METAPLASIA
- PROLIFERATIVE PATTERN ENDOMETRIUM
- ADENOMYOSIS
- RIGHT OVARY WITH PAPILLARY SEROUS ADENOCARCINOMA FOCALLY ASSOCIATED WITH A LOW- MALIGNANT POTENTIAL COMPONENT
- RIGHT FALLOPIAN TUBE STATUS-POST TUBAL LIGATION, NO TUMOR SEEN
- E) THREE (3) LEFT PELVIC LYMPH NODES, FREE OF TUMOR
- F) SIX (6) RIGHT PELVIC LYMPH NODES, FREE OF TUMOR
- G) THREE (3) RIGHT PERIAORTIC LYMPH NODES, FREE OF TUMOR
- H) TWO (2) LEFT PERIAORTIC LYMPH NODES, FREE OF TUMOR
- I) OMENTUM:
- NO TUMOR SEEN
- J) VERMIFORM APPENDIX WITH FIBROUS OBLITERATION OF TIP
- NO TUMOR SEEN

Source: NCI Genomic Data Commons file 1d4d0050-8755-4198-b29c-3a6572f24dde (TCGA-61-2110.D7A597DC-D607-4E20-90A9-A181D6C11D17.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).